Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A938, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A938-01A (Primary Tumor).

[page 1 of 6]
Surgical Pathology Consultation Report

Patient Name: [REDACTED]

MRN: [REDACTED]

DOB: [REDACTED]

Gender: M

Service: [REDACTED]

Visit #: [REDACTED]

Location: [REDACTED]

Facility: [REDACTED]

Accession #: [REDACTED]

Collected: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

Ordering MD: [REDACTED]

Copy To: [REDACTED]

Specimen(s) Received

1. Lymph-Node: ST19 Splenic nodes
2. Lymph-Node: ST18 Common Hepatic nodes
3. Lymph node: inf. pulm ligament st.9
4. Lymph node: lt tb angle st10L
5. Lymph node: subcarinal st.7
6. Soft Tissue: esophageal margin QS
7. Lymph node: Lt gastric nodes ST 17
8. Lymph node: paracardial nodes ST 16
9. Lymph node: paraesophageal St8
10. Soft Tissue: final gastric margin
11. Soft Tissue: final gastric margin open end=final margin
12. Soft Tissue: donuts

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Gastroesophageal junction C16.0
JY 4/18/14

Other Case Numbers

[REDACTED]

Diagnosis

1. Lymph node ST19 Splenic nodes: One lymph node negative for malignancy (0/1).
2. Lymph node ST18 Common Hepatic nodes: One lymph node negative for malignancy (0/1).
3. Lymph node inf. pulm ligament st.9: Three lymph nodes negative for malignancy (0/3).
4. Lymph node lt tb angle st10L: One lymph node negative for malignancy (0/1).
5. Lymph node subcarinal st.7: Two lymph nodes negative for malignancy (0/2).
6. Distal esophagus & proximal stomach; esophagogastrectomy:
- Invasive poorly differentiated adenocarcinoma, distal esophagus, arising in a Barrett's esophagus, extending to the painted esophageal adventitial margin, proximal and distal margins clear of invasive carcinoma, lymphovascular and perineural invasion not present, see synoptic data (1) and comment.
- Incidental GIST, gastric wall, see synoptic data (2).
7. Lymph node, left gastric nodes ST 17: Six lymph nodes negative for malignancy (0/6).
8. Lymph node paracardial nodes ST 16: Six lymph nodes negative for malignancy (0/6).

[page 2 of 6]
9. Lymph node paraesophageal St8: Four lymph nodes negative for malignancy (0/4).
10. Final gastric margin: Negative for malignancy.
11. Final gastric margin open end=final margin: Negative for malignancy.
12. Soft Tissue: donuts: Negative for malignancy.

Comment

The final lymph node tally in the synoptic is the total number of nodes retrieved in this procedure.

Synoptic Data

1 & 2.

Clinical History:	Barrett's esophagus
Specimen:	Esophagus Proximal stomach
Procedure:	Esophagogastrectomy
Primary Tumor Site:	Esophagogastric junction (EGJ)
Additional Sites Involved by Tumor:	None identified
Relationship of Tumor to Esophagogastric Junction:	Tumor midpoint lies in the distal esophagus and tumor involves the esophagogastric junction
Histologic Type:	Adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 3.8 cm
Microscopic Tumor Extension:	Tumor invades through the muscularis propria into the periesophageal soft tissue (adventitia)
Proximal Margin:	Uninvolved by invasive carcinoma Uninvolved by dysplasia
Distal Margin:	Uninvolved by invasive carcinoma Uninvolved by dysplasia
Circumferential (Adventitial) or Deep Margin:	Involved by invasive carcinoma
Treatment Effect:	No prior treatment
*Lymph-Vascular Invasion:	Not identified: .
Perineural Invasion:	Not identified: .
TNM Descriptors:	Not applicable: .
Primary Tumor (pT):	pT3: Tumor invades adventitia
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 24 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable: .
Additional Pathologic Findings:	*Intestinal metaplasia (Barrett's esophagus)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Preresection Treatment:	No therapy
Procedure:	Resection, type: Esophagogastrectomy for esophageal carcinoma
Primary Tumor Site:	Stomach, NOS
Additional Sites Involved by Tumor:	Not identified
Tumor Focality:	Unifocal
GIST Subtype:	Spindle cell
Histologic Grade:	G1: Low grade; mitotic rate less than or equal to 5 / 50 HPF
Risk Assessment:	Low risk

[page 3 of 6]
Surgical Pathology Consultation Report

Tumor Size:	Greatest dimension: 0.8 cm
Margins:	Negative for GIST
	Distance of tumor from closest margin cannot be assessed: grossly submitted as lymph node
Mitotic Rate:	0 /50 high-power fields (HPF)
Necrosis:	Not identified
Immunohistochemical Studies:	KIT (CD117) Positive
	Others: DOG1 +ve; MSA, DESMIN, S100 -ve.
Molecular Genetic Studies:	Submitted for analysis; results pending: .
TNM Descriptors:	Not applicable: .
Primary Tumor (pT):	pT1: Tumor 2 cm or less
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
Distant Metastasis (pM):	Not applicable: .
Additional Pathologic Findings:	KI67 <2%

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Clinical History

ESOPHAGEAL CANCER

Gross Description

1. The specimen container labeled with the patient's name and as "ST 19 splenic nodes" contains multiple piece(s) of fatty tissue measuring from 1.3 x 0.8 x 0.5 cm to 2.5 x 1.2 x 0.8 cm received in 10% buffered formalin. Two probable lymph node(s) are identified measuring 0.3 x 0.3 x 0.2 cm and 0.6 x 0.4 x 0.3 cm. The specimen is submitted as follows:
1A two probable lymph nodes.

2. The specimen container labeled with the patient's name and as "ST 18 common hepatic nodes" contains one piece(s) of fatty tissue measuring 2.6 x 1 x 1 cm received in 10% buffered formalin. One lymph node(s) is identified measuring 0.9 x 0.7 x 0.2 cm. The specimen is submitted as follows:
2A one lymph node.

3. The specimen container labeled with the patient's name and as "inferior pulmonary ligament ST 9" contains one piece(s) of fatty tissue measuring 1 x 0.7 x 0.2 cm received in 10% buffered formalin. One probable lymph node(s) is identified measuring 0.3 x 0.3 x 0.1 cm.
3A specimen submitted in toto.

4. The specimen container labeled with the patient's name and as "left TB angle ST10L" contains one gray-black lymph node measuring 1.8 x 1.1 x 0.3 cm received in 10% buffered formalin.
4A one lymph node in toto.

5. The specimen container labeled with the patient's name and as "subcarinal ST7" contains two gray-black lymph nodes measuring 0.4 x 0.4 x 0.2 cm and 2.8 x 2 x 0.9 cm received in 10% buffered formalin.. The specimen is submitted in toto as follows:
5A one lymph node.
5B, 5C one bisected lymph node

6. RESECTION SPECIMEN: Esophageal margin qs

FIXATION: fixed

DIMENSIONS:

Length of stomach, resection: 5.3 cm.

[page 4 of 6]
Surgical Pathology Consultation Report

Circumference of stomach fully opened: 7 cm
Circumference of proximal gastric margin: 18 cm
Length of tubular esophagus: 5.2 cm
Circumference of tubular esophagus: 4.5 cm

TUMOR

LOCATION:

- Gastric region: Distal esophagus/GE junction
- most of tumor mass located in distal esophagus

- CONFIGURATION: Ulcerated

- **DIMENSIONS:** Diameters: 3.8 x 2.9 cm
Depth: 0.5 cm

- DESCRIPTIVE CHARACTERISTICS: Firm, tan and ill-defined on cut surface

- PERFORATION: No

- DISTANCE FROM MARGINS:

- PROXIMAL: 0.8 cm
- DISTAL: 1.5 cm
- RADIAL: 0.8 cm (nonperitonealized soft tissue margin closest to deepest tumor penetration)

ESTIMATED DEPTH OF INVASION: Submucosal

LESIONS IN NONCANCEROUS STOMACH: None identified

LYMPH NODES: One perigastric lymph node is identified measuring 0.5 x 0.5 x 0.4 cm. No adventitial lymph nodes identified

Tumor and normal tissue stored frozen

Frozen section done: Yes, esophageal resection margin

Representative Sections:

- 6A esophageal resection margin, en face, frozen section block resubmitted.
- 6B perpendicular section closest gastric margin.
- 6C-6T sequential perpendicular sections of tumor in toto (as shown in diagram.)
- 6U further section of gastric margin.
- 6V, 6W, random gastric wall.
- 6X one perigastric lymph node, bisected
- 6Y the remaining perigastric fibrofatty tissue.
- 6Z the adventitia of tissue, in toto

7. The specimen container labeled with the patient's name and as "left gastric nodes ST17" contains one piece(s) of fatty tissue measuring 6 x 4 x 1.7 cm received in 10% buffered formalin. Multiple lymph node(s) are identified measuring from 0.1 x 0.1 x 0.1 cm to 0.4 x 0.3 x 0.2 cm. The specimen is submitted as follows:

7A, 7B multiple lymph nodes each block.

8. The specimen container labeled with the patient's name and as "pericardial nodes ST16" contains one piece(s) of fatty tissue measuring 4 x 3.3 x 1.5 cm received in 10% buffered formalin. Multiple lymph node(s) are identified measuring from 0.2 x 0.2 x 0.1 cm to 0.7 x 0.5 x 0.4 cm. The specimen is submitted as follows:

- 8A multiple lymph nodes.
- 8B, one lymph node bisected

[page 5 of 6]
Surgical Pathology Consultation Report

9. The specimen container labeled with the patient's name and as "paraesophageal ST8" contains three piece(s) of fatty tissue measuring from 2.8 x 1.5 x 1 cm to 4 x 3.5 x 1 cm received in 10% buffered formalin. Multiple lymph node(s) are identified measuring from 0.3 x 0.2 x 0.2 cm to 1.2 x 1.2 x 0.4 cm. The specimen is submitted as follows:

9A, 9B, multiple lymph nodes each block.

9C one lymph node bisected

10. The specimen container labeled with the patient's name and as "final gastric margin" contains a stapled portion of stomach measuring 4.5 x 3.8 by 1.8 cm in maximum dimensions received in 10% buffered formalin. The staple line measures 8 cm in overall length. The serosal surface is smooth and grossly unremarkable. The mucosa shows normal rugae and has a small amount of blood clot present on it. Representative sections are submitted as follows:

10A, 10B the resection margin, en face (in toto.)

10C random representative sections

11. The specimen container labeled with the patient's name and as "final gastric margin open end final margin" contains a portion of unoriented gastric wall with a stapled end and an opened end received in 10% buffered formalin. It measures 2 cm in length by 3.2 cm in width. The staple line measures 2.5 cm in length and the open end measures 3 cm in circumference. There are membranous adhesions on the serosal surface. The mucosa is grossly unremarkable. Representative sections are submitted as follows:

11A the stapled margin, en face

11B the open end en face

12. The specimen container labeled with the patient's name and as "donuts" contains two pieces of bowel (one ring shaped) measuring 1.5 x 1.5 x 0.3 cm and 2.3 x 1.6 x 0.8-cm received in 10% buffered formalin. No gross abnormality noted. Submitted in toto as follows:

12A, 12B the larger ring-shaped piece bisected.

12C the smaller piece trisected

Quick Section Diagnosis

6. Esophageal margin negative for carcinoma; Barrett's esophagus present

Reported to OR

Molecular Diagnostics

Status: Signed Out

Date Reported:

Interpretation

A Val559Gly mutation in exon 11 of the KIT gene is present in this sample using PCR and bi-directional sequencing analysis. There is no evidence for the presence of a PDGFRA mutation.

DNA was extracted from paraffin embedded soft tissue: esophageal margin QS, part 6, block X, and amplified using primers specific for exons 9, 11, 13 and 17 of the KIT gene, and exons 12 and 18 of the PDGFRA gene. The PCR products were purified, sequenced and then compared with the NCBI reference sequence.

The presence of an X06182.1:c.1676T>G (p.Val559Gly) mutation in exon 11 of the KIT gene was detected by PCR and sequencing. No mutation was detected in exons 12 and 18 of the PDGFRA gene. A polymorphism, in the PDGFRA gene was also identified in this patient.

The lower limit of mutation detection by sequencing is 10-15%.

This analysis is based on our current knowledge of the KIT or PDGFRA activating mutations and their association with GISTs. Demonstration of a mutation in the KIT or PDGFRA gene supports the diagnosis of GIST and predicts response to imatinib. This test was developed and its performance characteristics determined by

[page 6 of 6]
Surgical Pathology Consultation Report

It has not been cleared or approved by the U.S.

FDA.

Kim TW, et al. Clinical Cancer Research. 2004; 10: 3076-3081. Heinrich MC, et al. J Clin Oncol. 2003; 21(23): 4342-4349. Heinrich MC, et al. Science 2003; 299:708-710. Chen LL, et al. Curr Oncol Rep. 2005; 7(4): 293-299. Blackstein ME, et al. Can J Gastroenterol. 2006; 20(3):157-163

Source: NCI Genomic Data Commons file bab4adf0-668d-4144-9694-af24fcc2ba84 (TCGA-JY-A938.572009C2-F1D9-42A0-8489-4066729BA0E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).